Somatic mutation profile of tumor specimen TCGA-T2-A6WX-01A (aliquot TCGA-T2-A6WX-01A-12D-A34J-08) from TCGA case TCGA-T2-A6WX, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; Tumor grade: G1; Age at diagnosis: 73.9 years (27,005 days).
Specimen TCGA-T2-A6WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6d0d33d-f0a2-499a-b0bb-4e6a59dbd06c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T2-A6WX-10B (Blood Derived Normal), aliquot TCGA-T2-A6WX-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05b93953-b0bb-499e-b0d4-e071c36838ab

The open-access MAF lists 200 somatic variants for this specimen: 150 protein-altering or splice-affecting, 45 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 45, Nonsense Mutation 13, Intron 3, Splice Region 2, Frame Shift Del 2, RNA 1, Splice Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALC | c.1884dup p.W629Mfs*9 | Frame Shift Ins (INS) | VAF 60/278 reads (22%) | catalogued as rs1336726861; ClinVar: likely pathogenic; called by mutect2, varscan2
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD16A | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65452413; called by muse, mutect2
- AC068580.4 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.948); catalogued as COSV99362175; called by muse, mutect2, varscan2
- ACP2 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99922060; called by muse, mutect2, varscan2
- ADAD1 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56641632, COSV99634960; called by muse, mutect2, varscan2
- AHCYL2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100272749; called by muse, mutect2, varscan2
- ALG12 | c.713C>G p.P238R | Missense Mutation (SNP) | VAF 21/112 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV100426935, COSV58206291; called by muse, mutect2, varscan2
- AMPH | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs147284975; called by muse, mutect2, varscan2
- ANKRD11 | c.2716C>T p.R906* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV56353984; called by muse, mutect2, varscan2
- APC | c.4480G>C p.E1494Q | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57327819, COSV57327829, COSV57380546, COSV57394087, COSV99964417; called by muse, mutect2, varscan2
- AQP6 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.886); catalogued as COSV100210044, COSV59646670; called by muse, mutect2, varscan2
- ARCN1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV50615450; called by muse, mutect2, varscan2
- ARHGEF10 | c.556G>A p.E186K (on ENST00000398564; = p.X161_splice on NM_014629.4) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.026); catalogued as COSV100033432; called by muse, mutect2, varscan2
- ASB10 | c.871G>A p.D291N (on ENST00000420175 / NM_001142459.2; = p.D276N on NM_080871.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs371002840; called by muse, mutect2, varscan2
- BRPF3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100325497; called by muse, mutect2, varscan2
- C1orf52 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV99640854; called by muse, mutect2, varscan2
- CA5A | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99990319; called by mutect2, varscan2
- CALB2 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV56939425, COSV56942422; called by muse, mutect2, varscan2
- CASP8 | c.29T>C p.I10T | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51852343; called by muse, mutect2, varscan2
- CCAR2 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99373757; called by muse, mutect2, varscan2
- CCDC62 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1451324647, COSV99456498; called by muse, mutect2, varscan2
- CCNA1 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.258); catalogued as COSV55222672, COSV99714179; called by muse, mutect2, varscan2
- CD22 | c.1298G>C p.R433P | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99322707, COSV99323560; called by muse, mutect2, varscan2
- CDH18 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV56965374; called by muse, mutect2, varscan2
- CFAP70 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV100160032; called by muse, mutect2, varscan2
- CHIT1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55147007, COSV99704970; called by muse, mutect2, varscan2
- CIC | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs1456325922, COSV99358707; called by muse, mutect2, varscan2
- CLIP2 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99790832; called by muse, mutect2
- COL6A3 | c.6959G>A p.G2320E | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55090329; called by muse, mutect2, varscan2
- COL6A3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99795825; called by muse, mutect2, varscan2
- CORIN | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs182430182, COSV56688469; called by muse, mutect2, varscan2
- CREBBP | c.5282C>G p.S1761* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52124301, COSV52144650; called by muse, mutect2, varscan2
- CRY2 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV69888227; called by muse, mutect2, varscan2
- CTSO | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as COSV101467825; called by muse, mutect2, varscan2
- CYP3A4 | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100315349; called by muse, mutect2, varscan2
- CYRIB | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101309565; called by muse, mutect2, varscan2
- DHX36 | c.1114G>C p.E372Q | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100273196; called by muse, mutect2, varscan2
- DMD | c.5099C>A p.T1700K | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100817166; called by muse, mutect2, varscan2
- DMRTA1 | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100364597; called by muse, mutect2, varscan2
- DNAH8 | c.12113T>C p.L4038P | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100542730; called by muse, mutect2, varscan2
- DSP | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1337095425, COSV65793161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDNRA | c.1234C>G p.Q412E | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60099940; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100348785; called by muse, mutect2, varscan2
- FANCF | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV100541744; called by muse, mutect2, varscan2
- FLNB | c.6626G>A p.G2209E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99911306; called by muse, mutect2, varscan2
- FSHR | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100436336, COSV100438240; called by muse, mutect2, varscan2
- GCN1 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100324489; called by muse, mutect2, varscan2
- GFOD2 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.299); catalogued as COSV99263306; called by muse, mutect2, varscan2
- GIGYF1 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99308602; called by muse, mutect2, varscan2
- GIMAP8 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV56230742; called by muse, mutect2, varscan2
- GPR149 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV101078018; called by muse, mutect2, varscan2
- GPRASP1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100850883; called by muse, mutect2, varscan2
- GPRC6A | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113902; called by muse, mutect2, varscan2
- GZF1 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100582343; called by muse, mutect2, varscan2
- H2BC15 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100356855, COSV57586152; called by muse, mutect2, varscan2
- HENMT1 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as COSV100898633; called by muse, mutect2, varscan2
- HMCN1 | c.8398G>A p.E2800K | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99622543; called by muse, mutect2, varscan2
- HOOK1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as COSV100968943; called by muse, mutect2, varscan2
- HUWE1 | c.13030C>G p.Q4344E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99470170; called by muse, mutect2, varscan2
- ITGA10 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100994630; called by muse, mutect2, varscan2
- ITGA2B | c.2886C>G p.N962K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV99288440; called by muse, mutect2, varscan2
- ITPR2 | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs992031932, COSV101189763; called by muse, mutect2, varscan2
- KCNAB3 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as COSV100375889; called by muse, mutect2, varscan2
- KDM4B | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1252117669, COSV99345283; called by muse, mutect2, varscan2
- KDM5B | c.4409C>A p.S1470* | Nonsense Mutation (SNP) | VAF 58/226 reads (26%) | catalogued as COSV52505600, COSV99349892; called by muse, varscan2
- KIF11 | c.2351G>A p.R784K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99585559; called by muse, varscan2
- KIF21B | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100143256; called by muse, mutect2, varscan2
- KRT33A | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as rs142473669, COSV50373990; called by muse, mutect2, varscan2
- LANCL3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV101065413; called by muse, mutect2, varscan2
- LCT | c.5131G>C p.D1711H | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV99928289; called by muse, mutect2, varscan2
- LEF1 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV99489085; called by muse, mutect2, varscan2
- LIMK2 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100057717; called by muse, varscan2
- LRBA | c.7466G>C p.R2489T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100840765; called by muse, mutect2, varscan2
- LRRC49 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs767081330, COSV99536791; called by muse, mutect2, varscan2
- MAP9 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100250646; called by muse, mutect2, varscan2
- MBTPS1 | c.2897G>A p.R966Q | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.063); catalogued as rs1477942796, COSV100597260, COSV100597821; called by muse, mutect2, varscan2
- MYCBP2 | c.12250A>G p.K4084E (on ENST00000357337; = p.K4122E on NM_015057.5) | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100628883; called by muse, mutect2, varscan2
- MYH14 | c.5054G>A p.R1685Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as rs747204998, COSV99221427; called by muse, mutect2
- NETO2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV100292323; called by muse, mutect2, varscan2
- NFKBIZ | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as rs1295701275, COSV100396871; called by muse, mutect2, varscan2
- NLRX1 | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1048805443, COSV99423501; called by muse, mutect2, varscan2
- NOTCH4 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV100900264; called by muse, mutect2, varscan2
- NRP2 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 55/121 reads (45%) | catalogued as COSV99783245; called by muse, mutect2, varscan2
- NUDT22 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as rs751953613, COSV99655587; called by muse, mutect2, varscan2
- OBSCN | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs781565321, COSV52770685; called by muse, mutect2, varscan2
- OR2T1 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822237, COSV63541456; called by muse, mutect2, varscan2
- OR52N4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV57890290; called by muse, mutect2, varscan2
- OXA1L | c.1396C>T p.L466F (on ENST00000285848; = p.L406F on NM_005015.5) | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99590941; called by muse, mutect2, varscan2
- PC | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750387125, COSV63079693, COSV63081991; called by muse, mutect2, varscan2
- PDE4B | c.1652A>T p.D551V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100301740; called by muse, mutect2
- PIAS2 | c.1303A>G p.K435E | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100244864; called by muse, mutect2, varscan2
- PLCB4 | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53797253; called by muse, mutect2, varscan2
- PLCL1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as rs376872615, COSV101407230, COSV70886021; called by muse, mutect2, varscan2
- POLR3GL | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100996713; called by muse, mutect2
- PPP1R3A | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99491699; called by muse, mutect2, varscan2
- PRICKLE1 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV100566041; called by muse, mutect2, varscan2
- PRPF3 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100254401; called by muse, mutect2, varscan2
- PRPF3 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100254402; called by muse, varscan2
- PRSS23 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as rs774235432, COSV54707245, COSV99722243; called by muse, mutect2, varscan2
- PTH1R | c.315G>A p.G105= | Splice Region (SNP) | VAF 10/35 reads (29%) | catalogued as rs370990147; called by muse, mutect2, varscan2
- RABGAP1 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100438357; called by muse, mutect2, varscan2
- RALYL | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV101568938, COSV72823131; called by muse, mutect2, varscan2
- REPS1 | c.1488G>C p.K496N | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99238306; called by muse, mutect2, varscan2
- RNF14 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs765971131, COSV100641285, COSV61662868; called by muse, mutect2, varscan2
- RNF213 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV100172838; called by muse, mutect2, varscan2
- RRBP1 | c.2545G>A p.E849K (on ENST00000377813 / NM_001365613.2; = p.E416K on NM_004587.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99853435; called by muse, mutect2, varscan2
- RRS1 | c.57G>C p.E19D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.345); catalogued as COSV99397491; called by muse, mutect2, varscan2
- SACS | c.13390G>A p.D4464N | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as CM113214, COSV101207120; called by muse, mutect2, varscan2
- SCIMP | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412724558, COSV101275718; called by muse, mutect2, varscan2
- SEMA6D | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316288; called by muse, mutect2, varscan2
- SERPINE1 | c.777C>G p.F259L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99776511; called by muse, mutect2, varscan2
- SESN2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99455220; called by muse, mutect2, varscan2
- SHOC1 | c.3836C>T p.S1279L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs750456198, COSV59498341, COSV59500993; called by muse, mutect2, varscan2
- SIDT1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753164668, COSV99332884; called by muse, mutect2, varscan2
- SMG1 | c.6925G>C p.E2309Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101244923; called by muse, mutect2, varscan2
- SORCS1 | c.2283G>T p.Q761H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV53898419, COSV99542179; called by muse, mutect2, varscan2
- SPTBN2 | c.5341G>A p.E1781K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777756110, COSV100017840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRRM4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1330185164, COSV99937498; called by muse, mutect2, varscan2
- STAM2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99812742; called by muse, mutect2, varscan2
- TDRKH | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs773992753, COSV100917825, COSV64316007; called by muse, mutect2, varscan2
- TDRKH | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100917826; called by muse, mutect2, varscan2
- TGM4 | c.999G>C p.W333C | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1318181375, COSV99942085; called by muse, varscan2
- TKFC | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as COSV99582148; called by muse, mutect2, varscan2
- TMC6 | c.1857C>G p.I619M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV100129823; called by muse, mutect2
- TMEM145 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99233984; called by muse, mutect2, varscan2
- TMEM241 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV101271673; called by muse, varscan2
- TMEM255A | c.204C>T p.L68= | Splice Region (SNP) | VAF 30/124 reads (24%) | catalogued as COSV59032377; called by muse, mutect2, varscan2
- TNFAIP1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs782352267, COSV99134650; called by muse, mutect2, varscan2
- TNK1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.177); catalogued as rs757368247, COSV100294665; called by muse, varscan2
- TNK1 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100294667; called by muse, varscan2
- TRAF3IP1 | c.1984G>T p.D662Y | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100966683; called by muse, mutect2, varscan2
- TRPC5 | c.2225A>C p.N742T | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99458978; called by muse, mutect2, varscan2
- TTC1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.023); catalogued as COSV99180625; called by muse, mutect2, varscan2
- TXNDC2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV100045624; called by muse, mutect2, varscan2
- UNC5B | c.553-1G>A p.X185_splice | Splice Site (SNP) | VAF 7/182 reads (4%) | catalogued as COSV100099997; called by muse, mutect2
- USP42 | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100083848; called by muse, mutect2, varscan2
- VSTM4 | c.457G>A p.V153I (on ENST00000332853 / NM_001031746.5; = p.G153R on NM_144984.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100039052; called by muse, mutect2, varscan2
- XIRP2 | c.264G>T p.R88S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); catalogued as COSV99737026; called by muse, mutect2, varscan2
- ZFP90 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.643); catalogued as COSV101238678, COSV104433087; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV100459956; called by muse, mutect2, varscan2
- ZNF394 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.413); catalogued as COSV100459954, COSV58743479; called by muse, mutect2, varscan2
- ZNF44 | c.301G>C p.D101H (on ENST00000356109 / NM_001164276.2; = p.D53H on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1401922612, COSV100633424; called by muse, mutect2
- ZNF513 | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99277154; called by muse, mutect2, varscan2
- ZNF558 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1555768944, COSV100037768, COSV56864379; called by muse, mutect2, varscan2
- ZNF606 | c.970C>G p.Q324E | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV100356990, COSV62049713; called by muse, mutect2, varscan2
- CRYBG1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by mutect2, varscan2
- CWC25 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- KDM1B | c.244del p.W82Gfs*82 | Frame Shift Del (DEL) | VAF 22/133 reads (17%) | called by mutect2, pindel, varscan2
- MYOF | c.1137_1147del p.T380Nfs*8 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- ABCD1 | c.738C>T p.I246= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV54383512; called by muse, mutect2, varscan2
- ACP2 | c.97C>T p.L33= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1233576068, COSV99922064; called by muse, mutect2, varscan2
- AHNAK | c.10140A>T p.I3380= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV99945165; called by muse, mutect2, varscan2
- APOL5 | c.1301G>A p.*434= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99968315; called by muse, mutect2
- C6orf15 | c.597C>T p.L199= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99456546; called by muse, mutect2, varscan2
- CAPN10 | c.1428C>T p.D476= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as rs754583407, COSV54380893; called by muse, varscan2
- CCDC142 | c.885C>T p.L295= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1009681406, COSV99281826; called by muse, mutect2, varscan2
- CLEC17A | c.306G>A p.R102= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100354995; called by muse, mutect2
- COL20A1 | c.93C>T p.L31= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs750394568, COSV100489752; called by muse, mutect2, varscan2
- DLEC1 | c.4008C>G p.L1336= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as COSV100341131; called by muse, mutect2, varscan2
- ENPP7 | c.816C>T p.D272= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as rs1490901920, COSV100093123; called by muse, mutect2, varscan2
- FRY | c.8208C>T p.I2736= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as rs756328216, COSV66580253; called by muse, mutect2, varscan2
- GMFB | c.45G>A p.V15= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as COSV100794423; called by muse, mutect2, varscan2
- GRIA2 | c.1194C>A p.T398= | Silent (SNP) | VAF 40/212 reads (19%) | catalogued as COSV99642470; called by muse, mutect2, varscan2
- HECTD1 | c.3687C>T p.L1229= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs1399182155, COSV101237288; called by muse, mutect2, varscan2
- HECTD4 | c.10407C>T p.V3469= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV101106452; called by muse, mutect2, varscan2
- HEPH | c.2607C>T p.G869= (on ENST00000343002; = p.G602= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100293889; called by muse, mutect2, varscan2
- IGFBPL1 | c.639C>G p.V213= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100890732; called by muse, mutect2, varscan2
- INTS6 | c.21G>T p.L7= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV100246842; called by muse, mutect2, varscan2
- KCNJ6 | c.765G>A p.L255= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV55713779, COSV99898882; called by muse, mutect2, varscan2
- LMNTD2 | c.342G>A p.Q114= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as rs896133235, COSV99529297; called by muse, mutect2, varscan2
- LRRC30 | c.717C>G p.L239= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV101274364; called by muse, mutect2, varscan2
- LRRC71 | c.972A>G p.K324= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1235612022, COSV61656113; called by muse, mutect2
- MAGEB18 | c.627G>A p.L209= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100305244; called by muse, mutect2, varscan2
- MAGEC1 | c.912G>A p.Q304= | Silent (SNP) | VAF 81/555 reads (15%) | catalogued as COSV99594613; called by muse, mutect2, varscan2
- NEBL | c.2598C>G p.L866= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV101009046; called by muse, mutect2, varscan2
- NFASC | c.2151C>T p.S717= (on ENST00000339876 / NM_001378329.1; = p.S713= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs776480436, COSV100362452; called by muse, mutect2, varscan2
- NLN | c.2112G>A p.P704= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as rs766466206, COSV101114069; called by muse, mutect2, varscan2
- PCNT | c.7593G>A p.T2531= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs372531708; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PSMD6 | c.396G>A p.V132= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99895826; called by muse, mutect2
- RASSF5 | c.375C>T p.F125= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100794996; called by muse, mutect2, varscan2
- RET | c.2790G>A p.T930= | Silent (SNP) | VAF 29/228 reads (13%) | catalogued as rs746599792, COSV100391952; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHOV | c.447C>T p.D149= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs913869128, COSV99592001; called by muse, mutect2, varscan2
- RPL11 | c.24G>A p.E8= (on ENST00000374550 / NM_001199802.1; = p.E9= on NM_000975.5) | Silent (SNP) | VAF 29/144 reads (20%) | catalogued as rs1386197283, COSV100999654; called by muse, mutect2, varscan2
- SARDH | c.1179G>C p.L393= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100898645; called by muse, mutect2, varscan2
- SDK1 | c.2052C>T p.H684= | Silent (SNP) | VAF 52/206 reads (25%) | catalogued as rs550278515, COSV101269602, COSV67373879; called by muse, mutect2, varscan2
- SMTNL1 | c.1356G>A p.V452= (on ENST00000399154; = p.V489= on NM_001105565.2) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1419187151, COSV99761727; called by muse, mutect2, varscan2
- TCOF1 | c.1233G>A p.Q411= (on ENST00000377797 / NM_001135243.1; = p.Q334= on NM_000356.4) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1368664106, COSV100076630; called by muse, mutect2, varscan2
- TRIML1 | c.18G>C p.L6= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV100205591; called by muse, mutect2, varscan2
- TSSK2 | c.621C>T p.Y207= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as rs764088773, COSV99350534; called by muse, mutect2, varscan2
- UBA7 | c.1431C>G p.L477= | Silent (SNP) | VAF 55/278 reads (20%) | catalogued as rs749950771, COSV100339554; called by muse, mutect2, varscan2
- UTRN | c.8601C>T p.I2867= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100838089; called by muse, mutect2, varscan2
- WNT7A | c.639G>C p.T213= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV53198549, COSV99540739; called by muse, mutect2, varscan2
- ZMIZ1 | c.1368C>T p.S456= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs752723177, COSV100565813, COSV100566057; called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.867C>T p.G289= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as rs199985644, COSV53369066; called by muse, mutect2, varscan2
- HM13 | c.1035-943G>A | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100159212; called by muse, mutect2, varscan2
- MACF1 | c.15832-11445C>T | Intron (SNP) | VAF 21/107 reads (20%) | catalogued as COSV99240459; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2616C>G | RNA (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- STARD13 | c.170-18278G>T | Intron (SNP) | VAF 18/96 reads (19%) | catalogued as COSV99715334; called by muse, mutect2, varscan2
- TGIF1 | c.-267C>A | 5'UTR (SNP) | VAF 23/88 reads (26%) | catalogued as rs1225200165, COSV100394674; called by muse, mutect2, varscan2
